Somatic mutation profile of tumor specimen MP2PRT-PAVXTX-TMP1-A (aliquot MP2PRT-PAVXTX-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVXTX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,119 days).
Specimen MP2PRT-PAVXTX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a674fd9e-519b-4663-b58a-5dac5d59acc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVXTX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVXTX-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/baed5d7d-9650-4206-88ec-ee542108aa0c

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 8, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS3 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 97/412 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs1185511556, COSV99711063, COSV99712380; called by muse, mutect2, varscan2
- CCDC166 | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 208/880 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.216); catalogued as rs1554616603, COSV101545854; called by muse, mutect2, varscan2
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 152/369 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by muse, varscan2
- FBXL7 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 127/442 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs1352971111; called by muse, mutect2, varscan2
- MIGA1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs775316428, COSV66224688; called by muse, mutect2, varscan2
- SCAMP1 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as rs562453126; called by muse, mutect2, varscan2
- WFDC3 | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 148/321 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV54786459; called by muse, mutect2, varscan2
- TTC22 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 293/663 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- BOD1L1 | c.78G>A p.P26= | Silent (SNP) | VAF 12/377 reads (3%) | catalogued as rs1223923940; called by muse, mutect2
- DNAH17 | c.10011C>T p.R3337= | Silent (SNP) | VAF 117/463 reads (25%) | called by muse, mutect2, varscan2
- FIBIN | c.111C>T p.F37= | Silent (SNP) | VAF 163/607 reads (27%) | catalogued as rs747999392, COSV100590387; called by muse, mutect2, varscan2
- MANEAL | c.222G>A p.P74= | Silent (SNP) | VAF 156/476 reads (33%) | called by muse, varscan2
- MCF2 | c.1924T>C p.L642= | Silent (SNP) | VAF 33/63 reads (52%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.471G>A p.P157= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs575483661; called by muse, mutect2, varscan2
- ZIC5 | c.1071C>T p.P357= | Silent (SNP) | VAF 84/208 reads (40%) | called by muse, mutect2, varscan2
